Somatic mutation profile of tumor specimen 0DNRUS from CCDI case PBCBKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 17.3 years (6,331 days).
Specimen 0DNRUS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5491ff4b-6a24-48ea-a05f-cfe9b1cd1a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRTO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9f9f45e-ed87-4e7b-88ff-e0a7440039e8

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 4, Intron 2, Splice Site 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.4779G>A p.W1593* | Nonsense Mutation (SNP) | VAF 144/452 reads (32%) | catalogued as COSV69849453; called by muse, varscan2
- CCZ1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 88/494 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV100367933; called by muse, varscan2
- CDH23 | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.841); catalogued as rs374805957, COSV54940166; ClinVar: uncertain significance; called by muse, varscan2
- COL11A2 | c.1876G>A p.V626I (on ENST00000341947 / NM_080680.3; = p.V519I on NM_080679.2) | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.251); catalogued as rs755719124; called by muse, varscan2
- GIPC1 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 45/135 reads (33%) | catalogued as rs1476840205; called by muse, varscan2
- IDS | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781997631; called by muse, varscan2
- MYH1 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 60/546 reads (11%) | catalogued as COSV56858822; called by muse, varscan2
- NCOR1 | c.7264C>T p.R2422* | Nonsense Mutation (SNP) | VAF 140/453 reads (31%) | catalogued as COSV51968458; called by muse, varscan2
- PLAGL1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52788475, COSV99394089; called by muse, varscan2
- RP1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 76/700 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99606849; called by muse, varscan2
- SHROOM1 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs779025537; called by muse, varscan2
- SLC7A9 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753115478, COSV50083388; ClinVar: likely benign; called by muse, varscan2
- TULP4 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65577045; called by muse, varscan2
- DCDC1 | c.4816C>G p.P1606A (on ENST00000597505 / NM_001367979.1; = p.P713A on NM_020869.3) | Missense Mutation (SNP) | VAF 137/420 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, varscan2
- FPGT-TNNI3K | c.999G>C p.L333F | Missense Mutation (SNP) | VAF 172/568 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); called by muse, varscan2
- PLXNB3 | c.2518-1G>T p.X840_splice | Splice Site (SNP) | VAF 26/119 reads (22%) | called by muse, varscan2
- RNF38 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- SLC16A8 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- TAOK1 | c.563+1G>T p.X188_splice | Splice Site (SNP) | VAF 102/266 reads (38%) | called by muse, varscan2
- TMCO1 | c.181C>T p.L61F (on ENST00000612311 / NM_001256164.1; = p.L10F on NM_019026.6) | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); called by muse, varscan2
- TRIM51 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- CACTIN | c.1716C>T p.D572= | Silent (SNP) | VAF 50/94 reads (53%) | catalogued as rs771204896, COSV50268690; called by muse, varscan2
- MIPOL1 | c.1242G>A p.V414= | Silent (SNP) | VAF 172/538 reads (32%) | called by muse, varscan2
- MMP16 | c.990C>T p.T330= | Silent (SNP) | VAF 171/1198 reads (14%) | catalogued as rs1450279866, COSV99688135; called by muse, varscan2
- POU5F1 | c.792C>T p.A264= | Silent (SNP) | VAF 106/330 reads (32%) | called by muse, varscan2
- EBAG9 | c.*95A>C | 3'UTR (SNP) | VAF 61/218 reads (28%) | called by muse, varscan2
- IQSEC2 | c.738-10931C>T | Intron (SNP) | VAF 76/285 reads (27%) | called by muse, varscan2
- PRDM11 | chr11:45228231 T>A | 3'Flank (SNP) | VAF 4/40 reads (10%) | catalogued as rs924592266; called by muse, varscan2
- TECTB | c.941-70T>G | Intron (SNP) | VAF 40/92 reads (43%) | called by muse, varscan2
